Somatic mutation profile of tumor specimen C3L-07544-03 (aliquot CPT0430630007) from CPTAC case C3L-07544, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 49.7 years (18,151 days).
Specimen C3L-07544-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 047f0aaf-8e8a-48d5-a23a-9b3a3e5745cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07544-31 (Blood Derived Normal), aliquot CPT0430760001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/007ff89a-b589-417b-a012-ce295afdfcc0

The open-access MAF lists 83 somatic variants for this specimen: 63 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 17, Splice Region 3, Nonsense Mutation 3, Frame Shift Del 1, 5'UTR 1, Intron 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEBP1 | c.3029C>T p.P1010L | Missense Mutation (SNP) | VAF 21/624 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as rs1314503886, COSV99788807; called by muse, mutect2
- AMER1 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 26/663 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779325879, COSV57671673; called by muse, mutect2
- ASTN2 | c.1697T>G p.L566R (on ENST00000313400 / NM_001365069.1; = p.L515R on NM_014010.5) | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV100530200; called by muse, mutect2
- BCL9L | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 18/451 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52681952; called by muse, mutect2
- DOCK7 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52012972, COSV99065879; called by muse, mutect2
- EFNA3 | c.366C>A p.F122L | Missense Mutation (SNP) | VAF 22/472 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100860815; called by muse, mutect2
- ELFN2 | c.2297C>T p.T766M | Missense Mutation (SNP) | VAF 33/501 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs780401854, COSV68743765; called by muse, mutect2
- FAM71E1 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 34/533 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs758551324, COSV100618584; called by muse, mutect2
- HTR1A | c.1253A>C p.K418T | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs758965208, COSV60500133, COSV60503073; called by muse, mutect2
- IRX1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV57359619; called by muse, mutect2
- JHY | c.2013G>A p.T671= | Splice Region (SNP) | VAF 15/200 reads (8%) | catalogued as rs199645772, COSV57075541; called by muse, mutect2
- KCNMA1 | c.2023T>G p.F675V | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99699506; called by muse, mutect2
- KIF19 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 17/610 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as rs1417800948; called by muse, mutect2
- KIF5C | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1020942504; called by muse, mutect2
- LRP1B | c.12314C>T p.S4105L | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV67247827; called by muse, mutect2
- LRRN2 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs371946869; called by muse, mutect2, varscan2
- MAGEE1 | c.1652T>G p.L551R | Missense Mutation (SNP) | VAF 22/535 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100819199, COSV63910080, COSV63912447; called by muse, mutect2
- NKX1-1 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 20/642 reads (3%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs1469500275; called by muse, mutect2
- PDILT | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 44/468 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs138528971, COSV100199452; called by muse, mutect2
- PMS1 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1437241846; called by muse, mutect2
- POP7 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 30/612 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.035); catalogued as rs755858590; called by muse, mutect2
- RSPO1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs751715004; called by muse, mutect2, varscan2
- SALL3 | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 29/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs533436270, COSV73306302, COSV73306776; called by muse, mutect2
- SLIT2 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.626); catalogued as COSV99073014; called by muse, mutect2
- SPANXD | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 25/530 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs373261190, COSV65152935; called by muse, mutect2
- STARD8 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 33/569 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199614519; called by muse, mutect2
- TGFBR1 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM148048; called by muse, mutect2
- VWDE | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1454518505; called by muse, mutect2
- WASHC5 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs749703625; called by muse, mutect2
- ZNF544 | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs769026512; called by muse, mutect2
- ZNF648 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 28/608 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV60571094; called by muse, mutect2
- ANOS1 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 19/402 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.068); called by muse, mutect2
- CBLN2 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 27/535 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); called by muse, mutect2
- CDH1 | c.977_988del p.I326_V329del | In Frame Del (DEL) | VAF 40/325 reads (12%) | called by mutect2, pindel
- CDH12 | c.1630A>G p.R544G | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- CLIP3 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- CLOCK | c.1449G>A p.Q483= | Splice Region (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- CXorf56 | c.320A>G p.K107R (on ENST00000536133 / NM_001170570.2; = p.K121R on NM_022101.4) | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.063); called by muse, mutect2
- CYP1B1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 19/546 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- DUOX2 | c.3920G>T p.C1307F | Missense Mutation (SNP) | VAF 13/435 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EIF2AK4 | c.4841G>A p.R1614K | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.992); called by muse, mutect2
- FBXW8 | c.766G>T p.A256S (on ENST00000309909; = p.A294S on NM_012174.1) | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.281); called by muse, mutect2
- FOXP1 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 20/606 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- GABRB1 | c.1330A>C p.T444P | Missense Mutation (SNP) | VAF 17/473 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.898); called by muse, mutect2
- GRIN3A | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 19/551 reads (3%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- IRAG2 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 11/327 reads (3%) | called by muse, mutect2
- KBTBD11 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 29/750 reads (4%) | called by muse, mutect2
- LRFN4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2
- LYPD1 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.048); called by muse, mutect2
- MAGEL2 | c.1007T>G p.L336R | Missense Mutation (SNP) | VAF 28/626 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC16 | c.7204A>C p.S2402R | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.08); called by muse, mutect2
- OR8H3 | c.86T>G p.F29C | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- PABPC4L | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- PCSK1N | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 29/668 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- PIGR | c.279del p.F93Lfs*3 | Frame Shift Del (DEL) | VAF 54/449 reads (12%) | called by mutect2, pindel, varscan2
- PIWIL1 | c.427A>G p.R143G | Missense Mutation (SNP) | VAF 32/473 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2
- PTPN5 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 24/480 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); called by muse, mutect2
- SEMA3D | c.389A>C p.N130T | Missense Mutation (SNP) | VAF 9/223 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- SFI1 | c.3634C>A p.Q1212K (on ENST00000400288 / NM_001007467.3; = p.Q1181K on NM_014775.4) | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- TRIM49 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- TRIP12 | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 17/327 reads (5%) | called by muse, mutect2
- UNC5D | c.2243T>A p.F748Y | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.651); called by muse, mutect2
- ZNF124 | c.33C>T p.N11= | Splice Region (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- BCL11A | c.1854G>A p.T618= (on ENST00000335712 / NM_001365609.1; = p.T652= on NM_018014.4) | Silent (SNP) | VAF 22/512 reads (4%) | catalogued as rs1355382688, COSV59623776; called by muse, mutect2
- BHLHE23 | c.543G>A p.A181= (on ENST00000370346; = p.A197= on NM_080606.4) | Silent (SNP) | VAF 32/578 reads (6%) | catalogued as COSV64846562; called by muse, mutect2
- FNDC1 | c.1956C>T p.R652= | Silent (SNP) | VAF 38/547 reads (7%) | catalogued as rs1024628421, COSV51939809; called by muse, mutect2
- MID1IP1 | c.234C>T p.G78= | Silent (SNP) | VAF 22/600 reads (4%) | called by muse, mutect2
- MRC2 | c.3342C>T p.S1114= | Silent (SNP) | VAF 17/347 reads (5%) | called by muse, mutect2
- MYOCD | c.1446C>T p.F482= | Silent (SNP) | VAF 23/480 reads (5%) | catalogued as rs747325331; called by muse, mutect2
- NKX2-1 | c.726C>T p.T242= | Silent (SNP) | VAF 39/644 reads (6%) | catalogued as rs886050483; ClinVar: uncertain significance; called by muse, mutect2
- NKX2-6 | c.645C>T p.R215= | Silent (SNP) | VAF 29/613 reads (5%) | called by muse, mutect2
- PCDH11X | c.3027C>G p.T1009= | Silent (SNP) | VAF 18/475 reads (4%) | catalogued as COSV53463458, COSV53466921; called by muse, mutect2
- PKD1 | c.7158C>T p.Y2386= | Silent (SNP) | VAF 20/344 reads (6%) | catalogued as rs1194528906, CM1210884; called by muse, mutect2
- PLXDC2 | c.1077T>C p.F359= | Silent (SNP) | VAF 11/324 reads (3%) | catalogued as COSV65900917; called by muse, mutect2
- RIMS2 | c.1342T>C p.L448= (on ENST00000666250 / NM_001348490.2; = p.L256= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 15/369 reads (4%) | catalogued as COSV51669105, COSV51676746; called by muse, mutect2
- RPS27 | c.75G>A p.V25= | Silent (SNP) | VAF 13/294 reads (4%) | called by muse, mutect2
- RYR3 | c.13426C>T p.L4476= (on ENST00000389232; = p.L4477= on NM_001036.6) | Silent (SNP) | VAF 20/477 reads (4%) | called by muse, mutect2
- SKOR1 | c.1590C>T p.S530= | Silent (SNP) | VAF 31/669 reads (5%) | catalogued as rs1415570554, COSV100408346; called by muse, mutect2
- SMIM10 | c.141G>A p.T47= | Silent (SNP) | VAF 40/670 reads (6%) | called by muse, mutect2
- ZNF319 | c.1713G>A p.A571= | Silent (SNP) | VAF 20/387 reads (5%) | catalogued as rs1280467444; called by muse, mutect2
- CYP3A5 | c.318+799T>A | Intron (SNP) | VAF 13/247 reads (5%) | called by muse, mutect2
- GPR75 | c.-205G>A | 5'UTR (SNP) | VAF 18/360 reads (5%) | called by muse, mutect2
- PSG3 | c.*118G>A | 3'UTR (SNP) | VAF 10/299 reads (3%) | called by muse, mutect2
